Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A88Y, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A88Y-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 1
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

A -year-old white male syncope episode and cause accident; had scape positive esophageal cancer. Operative Procedure/Tissue Submitted: Transhiatal esophagectomy.

PROCEDURE:

VERIFIED BY:

1. "Cervical esophageal margin." Received in formalin in a small container is a 2 x 2 x 2 cm segment of esophagus with a staple line at one end. Deep inked black.

1A. Esophageal cervical margin.

1B&1C. Remainder of specimen. Staple line retained.

2. "Thoracic esophagus." Received in formalin in a large container is an 8 cm esophagus with 6 cm stomach, with a 4.2 x 3.8 x 1.0 cm exophytic plaque with rolled edges arising from the distal esophagus. The mass involves approximately half of the esophagus diameter, abuts the gastroesophageal junction, and does not appear to extend into the stomach. The mass extends to 4.5 cm from the esophageal resection edge and 4.5 cm from the gastric resection edge. It extends through the mucosa to superficially involve the submucosa and extends to 0.6 cm of the deep resection margin. No muscularis propria involvement. The remainder of the GE junction has focal nodularity, and the remaining mucosa of the esophagus of the stomach is unremarkable.

2A. Mass.

2B-2G. Mass at deepest invasion.

2H. Nodular gastroesophageal junction.

2I. Unremarkable gastroesophageal junction, bisected.

2J. Unremarkable cervical esophagus.

2K&2L. Multiple possible lymph nodes.

2M. One possible lymph node.

3. "Gallbladder." Received in formalin in a medium container is a 12 x 5 x 5 cm distended gallbladder with 0.3 cm patent cystic duct and containing four bosselated yellow stones, 1.0 cm each. The mucosa is green, smooth, and diffusely thinned.

3A. Fundus and body with cystic duct.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma

ICD-O-3

Adenocarcinoma NOS 8140/3
Site: Distal third esophagus
C15.5

JA 11/12/13

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

If adenocarcinoma, it is arising in: Barrett's mucosa

Depth of invasion: Submucosa

Number of positive lymph nodes: 0/10

Extranodal metastasis: Unknown

Pattern of invasion: Expansile

Esophageal and gastric resection margins involved: No

Deep resection margin involved: No

TNM classification: T1 N0 M0

PROCEDURE:

VERIFIED BY:

1 and 2. Esophagus, resection: Invasive adenocarcinoma, arising in Barrett's mucosa, extending into the mid submucosa. Margins free. Ten lymph nodes negative for carcinoma. See template.

3. Gallbladder, resection: Cholelithiasis.

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Criteria:	10/10/13	Yes	No

Source: NCI Genomic Data Commons file 3dec10c5-f0e2-4966-b9b6-0d98cd033884 (TCGA-L5-A88Y.ADF270C6-0B79-4040-9571-0CCDEA4F1224.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).